Somatic mutation profile of tumor specimen MP2PRT-PATESM-TMP1-A (aliquot MP2PRT-PATESM-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATESM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,274 days).
Specimen MP2PRT-PATESM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c0a9dad-5562-4524-8c5c-a318d30f80a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATESM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATESM-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eed86913-66bb-43c0-9475-32c71fffa934

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472763, CM043852, CM970828; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 60/361 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs370233244, COSV55501144; called by muse, mutect2, varscan2
- CACNA1H | c.4022C>T p.A1341V | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs371030255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN7 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 57/628 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199613161; called by muse, mutect2
- CLDN17 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 57/932 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371701865, COSV54524849; called by muse, mutect2
- FAT3 | c.11378C>T p.P3793L | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs368909373; called by muse, mutect2, varscan2
- FLT3 | c.2516A>C p.D839A | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54045448; called by muse, mutect2, varscan2
- IGSF1 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100812058; called by muse, mutect2
- MAP3K15 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs759121677, COSV58841402; called by muse, mutect2
- PLXNB2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 128/526 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); catalogued as rs530051710, COSV63781223; called by muse, mutect2, varscan2
- SFRP1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1393341218; called by muse, mutect2
- SIAH3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 214/516 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs372951526; called by muse, varscan2
- SRGAP1 | c.3142G>A p.V1048M | Missense Mutation (SNP) | VAF 51/429 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); catalogued as rs146885491; called by muse, mutect2, varscan2
- TOP3B | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs149060942; called by muse, mutect2, varscan2
- DNMBP | c.3545G>T p.C1182F | Missense Mutation (SNP) | VAF 132/484 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.8928_8930del p.D2976del | In Frame Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- IGSF9B | c.3842G>A p.G1281D | Missense Mutation (SNP) | VAF 165/1050 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SHF | c.1245_1246dup p.Y416Sfs*17 | Frame Shift Ins (INS) | VAF 64/333 reads (19%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 96/623 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPK2 | c.12C>T p.S4= | Silent (SNP) | VAF 33/523 reads (6%) | catalogued as rs539459249; called by muse, mutect2
- DNAH9 | c.8772A>G p.E2924= | Silent (SNP) | VAF 44/329 reads (13%) | catalogued as COSV52336850, COSV52347439; called by muse, mutect2, varscan2
- DZIP1 | c.255C>T p.D85= | Silent (SNP) | VAF 149/649 reads (23%) | catalogued as rs369545970; called by muse, mutect2, varscan2
- HS3ST3A1 | c.762G>A p.T254= | Silent (SNP) | VAF 78/629 reads (12%) | called by muse, varscan2
- PCDHGB2 | c.525C>T p.N175= | Silent (SNP) | VAF 72/397 reads (18%) | catalogued as rs530891991; called by muse, mutect2, varscan2
- SNX21 | c.966G>T p.L322= | Silent (SNP) | VAF 224/567 reads (40%) | called by muse, mutect2, varscan2
